Somatic mutation profile of tumor specimen TCGA-CR-6492-01A (aliquot TCGA-CR-6492-01A-12D-2078-08) from TCGA case TCGA-CR-6492, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Hard palate; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 78.3 years (28,600 days).
Specimen TCGA-CR-6492-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac8b5933-8d01-4033-a367-8f7f8468476b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-6492-10A (Blood Derived Normal), aliquot TCGA-CR-6492-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5e35339-e824-4e01-b623-ab2a13d67009

The open-access MAF lists 54 somatic variants for this specimen: 39 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 14, Nonsense Mutation 6, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, varscan2
- AKAP6 | c.5516C>G p.P1839R | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.109); catalogued as COSV99799806, COSV99799876; called by muse, mutect2
- ATP10A | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV63512994; called by muse, mutect2
- CHL1 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99850713; called by muse, mutect2
- CRYBG3 | c.6898T>A p.Y2300N | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99476832; called by muse, mutect2
- DLK2 | c.811G>C p.V271L | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99767029; called by muse, mutect2
- DNMBP | c.2813A>T p.N938I | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV100143468; called by muse, mutect2, varscan2
- FAM83G | c.694C>A p.L232I | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.916); catalogued as COSV58756736; called by muse, mutect2
- FAT1 | c.10198C>T p.R3400* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as rs778150447, COSV101499250; called by mutect2, varscan2
- FAT1 | c.5080C>T p.Q1694* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as COSV101499251; called by muse, mutect2, varscan2
- GADD45GIP1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV100379776, COSV100380053; called by muse, mutect2
- IFT81 | c.699A>G p.L233= | Splice Region (SNP) | VAF 3/29 reads (10%) | catalogued as COSV99655881; called by muse, mutect2
- KEAP1 | c.1819G>C p.A607P | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99407607; called by muse, mutect2
- KIF14 | c.427A>G p.M143V | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100950771; called by muse, mutect2
- KLF11 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as COSV100007712; called by muse, mutect2
- LVRN | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.171); catalogued as COSV100773396; called by muse, mutect2
- MCM3AP | c.1535A>T p.K512I | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99386750; called by muse, mutect2
- NOTCH1 | c.1403T>G p.L468R | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99486771; called by muse, varscan2
- NPSR1 | c.928T>C p.Y310H | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.958); catalogued as COSV100706084; called by muse, mutect2
- NUP62 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV100351925; called by muse, mutect2
- OR5B12 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100222389; called by muse, mutect2
- PHC3 | c.2062A>G p.I688V (on ENST00000494943 / NM_001308116.2; = p.I700V on NM_024947.4) | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs529062268, COSV101520149; called by muse, mutect2, varscan2
- PIK3R1 | c.1391A>T p.D464V (on ENST00000521381 / NM_181523.3; = p.D194V on NM_181504.4) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99142335; called by muse, mutect2, varscan2
- PRDM1 | c.1660A>G p.R554G | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV100958684; called by muse, mutect2
- PRICKLE3 | c.1667C>A p.S556* | Nonsense Mutation (SNP) | VAF 16/98 reads (16%) | catalogued as COSV100889905; called by muse, mutect2, varscan2
- RARG | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs761508890, COSV100553360; called by muse, mutect2
- RASA1 | c.1478T>A p.L493* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV99169713; called by muse, mutect2, varscan2
- SLC8A3 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100776074; called by muse, mutect2, varscan2
- TBC1D32 | c.1666A>G p.I556V | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as COSV99249979; called by muse, mutect2
- TLN2 | c.189G>A p.W63* | Nonsense Mutation (SNP) | VAF 8/118 reads (7%) | catalogued as COSV100168639; called by muse, mutect2
- TOPORS | c.2185C>T p.H729Y | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.003); catalogued as COSV100859485; called by muse, mutect2
- TP63 | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1381645678, COSV99286401; called by muse, mutect2, varscan2
- TRIML2 | c.375G>C p.Q125H | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as COSV100455989, COSV58717236; called by muse, mutect2
- TTC17 | c.3280G>T p.V1094F | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV50008409, COSV99235103; called by muse, mutect2
- VAV1 | c.1367A>T p.D456V | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100408876; called by muse, mutect2
- VDR | c.1243A>G p.T415A | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99968661; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1744C>G p.L582V | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100047980; called by muse, mutect2, varscan2
- ZNF563 | c.1160A>T p.H387L | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99536511; called by muse, mutect2
- ZNF668 | c.274G>C p.A92P | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV100336573; called by muse, mutect2, varscan2
- ALDH5A1 | c.1089C>T p.A363= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as COSV100708764; called by muse, mutect2
- AMIGO2 | c.207G>A p.L69= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as rs761102831, COSV99873551; called by muse, mutect2
- BMPR2 | c.2232T>G p.P744= | Silent (SNP) | VAF 6/93 reads (6%) | catalogued as COSV101001401; called by muse, mutect2
- CELSR2 | c.4920C>T p.L1640= | Silent (SNP) | VAF 7/136 reads (5%) | catalogued as COSV54767219, COSV54774792; called by muse, mutect2
- CLSTN2 | c.1875G>C p.V625= | Silent (SNP) | VAF 5/84 reads (6%) | catalogued as COSV101515638; called by muse, mutect2
- COL18A1 | c.363C>T p.I121= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as COSV100700611; called by muse, mutect2
- GPR89A | c.1146A>G p.L382= | Silent (SNP) | VAF 25/238 reads (11%) | catalogued as rs1553697125, COSV100572404; called by muse, mutect2, varscan2
- HCFC1 | c.5976C>G p.G1992= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV100128758; called by muse, mutect2, varscan2
- KIF4B | c.213G>A p.P71= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs1304359892, COSV70527220, COSV70529755; called by muse, mutect2, varscan2
- MYH13 | c.5328A>G p.E1776= | Silent (SNP) | VAF 10/119 reads (8%) | catalogued as COSV99353332; called by muse, mutect2
- TNS2 | c.3489G>A p.L1163= (on ENST00000314250 / NM_170754.4; = p.L1173= on NM_015319.2) | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as COSV100036642; called by muse, mutect2
- TTC13 | c.1563C>T p.F521= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV100792901; called by muse, mutect2
- UBE2G2 | c.358C>T p.L120= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100446084; called by muse, mutect2, varscan2
- ZKSCAN3 | c.57G>A p.Q19= | Silent (SNP) | VAF 10/119 reads (8%) | catalogued as COSV99356864; called by muse, mutect2
- BRWD1 | c.6571+104T>C | Intron (SNP) | VAF 7/124 reads (6%) | catalogued as rs1232270502, COSV100313186; called by muse, mutect2
